Gene-level copy-number profile of tumor specimen TCGA-70-6723-01A from TCGA case TCGA-70-6723, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.8 years (24,035 days).
Specimen TCGA-70-6723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.51a12ccb-f5c5-4bdb-9450-e5ec7b7ca403.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-70-6723-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a975ddc2-0ffd-4de8-87b1-703ad6ab8b28

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 2,824; copy number 2: 25,169; copy number 3: 17,163; copy number 4: 9,191; copy number 5: 1,653; copy number 6: 2,022; copy number 7: 317; copy number 8: 444; copy number 9: 626; copy number 10: 15; copy number 11: 218; copy number 13: 87; copy number 16: 3; copy number 17: 6; copy number 18: 33; copy number 26: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-70-6723-01A-11D-1816-01): tumor purity 0.86, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,488,300–11,771,350, 5 genes (within-gene range 0–2): AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr4:21,464,700–21,853,188, 6 genes: MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr18:53,237,101–53,237,190, 1 gene: MIR4528.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,445 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–192,011,260, 1,382 genes, copy number 5–6 (broad region; genes not listed).
- chr2:49,563,388–52,961,452, 28 genes, copy number 5: AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr2:76,445,079–84,040,720, 64 genes, copy number 5 (broad region; genes not listed).
- chr2:200,510,008–203,738,912, 118 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr3:150,339,478–198,222,513, 844 genes, copy number 6–11 (broad region; genes not listed).
- chr4:45,323,253–48,780,322, 38 genes, copy number 5: THAP12P9, AC108043.1, RNU6-931P, RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P.
- chr5:58,198–3,181,487, 87 genes, copy number 5–6 (broad region; genes not listed).
- chr6:33,999,972–56,394,094, 478 genes, copy number 6–13 (within-gene range 4–13) (broad region; genes not listed).
- chr6:63,193,072–65,707,226, 24 genes, copy number 6: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr6:73,461,578–73,509,236, 1 gene, copy number 10 (within-gene range 4–10): MTO1.
- chr6:73,487,590–74,690,727, 12 genes, copy number 10 (within-gene range 4–10): RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7, AL357507.1, AL357563.1.
- chr6:78,604,467–87,329,278, 126 genes, copy number 8–13 (broad region; genes not listed).
- chr7:51,382,284–55,773,288, 63 genes, copy number 5–26 (broad region; genes not listed).
- chr7:56,631,739–69,125,376, 287 genes, copy number 5–8 (broad region; genes not listed).
- chr7:95,297,676–118,496,171, 474 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:51,817,575–54,420,725, 46 genes, copy number 11–17 (within-gene range 2–17): PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P.
- chr11:69,641,156–70,436,584, 27 genes, copy number 18: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 18: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr12:24,949,163–34,249,958, 206 genes, copy number 5–7 (broad region; genes not listed).
- chr13:69,408,216–70,564,437, 8 genes, copy number 6–7: SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1.
- chr14:18,333,726–22,190,713, 250 genes, copy number 8 (broad region; genes not listed).
- chr14:22,202,583–22,304,553, 8 genes, copy number 8: TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39.
- chr14:104,138,723–106,875,071, 254 genes, copy number 5 (broad region; genes not listed).
- chr17:9,644,698–9,729,687, 1 gene, copy number 5 (within-gene range 4–5): USP43.
- chr17:9,764,186–19,022,595, 294 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:52,390,515–54,365,634, 12 genes, copy number 5 (within-gene range 3–5): LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1.
- chr18:22,699,481–24,708,542, 48 genes, copy number 5 (within-gene range 4–5): AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57.
- chr18:26,906,481–27,595,164, 10 genes, copy number 5–6 (within-gene range 3–6): CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2.
- chr18:30,954,820–37,565,827, 115 genes, copy number 5 (broad region; genes not listed).
- chr19:15,944,299–16,892,606, 55 genes, copy number 5: OR10H4, CYP4F9P, LINC00661, AC004790.2, LINC00905, SNX33P1, AC004790.1, OR1AB1P, LINC01855, TPM4, AC008894.3, AC008894.1, RAB8A, AC008894.2, HSH2D, CIB3, FAM32A, AC020911.1, Metazoa_SRP, AC020911.3, AP1M1, AC020911.2, KLF2, AC020917.3, EPS15L1, AC020917.4, AC020917.1, AC020917.2, CALR3, AC008764.1, C19orf44, CHERP, RN7SL146P, AC008764.6, SLC35E1, AC008764.3, AC008764.5, AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A, AC008737.2, NWD1, AC008737.3, SIN3B, AC008737.1, F2RL3.
- chr19:16,907,462–16,910,784, 2 genes, copy number 5: RN7SL835P, RN7SL823P.
- chr19:22,501,699–24,163,425, 77 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,226. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
